CCDI case PBCMVV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/b6345132-07ca-404b-bb80-a1d2299b2407

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Mesenchymal chondrosarcoma: ICD-O-3 morphology code: 9240/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 10.7 years (3,909 days).

Biospecimens (3 samples)
- Sample 0DVJNU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVJO6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVJOK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
